Somatic mutation profile of tumor specimen ALCH-B1TL-TTR1-A (aliquot ALCH-B1TL-TTR1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B1TL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.1 years (23,771 days).
Specimen ALCH-B1TL-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db84fa25-94a0-4b84-bd39-9bcdaa889714.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TL-NB1-A (Blood Derived Normal), aliquot ALCH-B1TL-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/791de1d1-1faa-434b-8252-9bd886da399b

The open-access MAF lists 812 somatic variants for this specimen: 582 protein-altering or splice-affecting, 146 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 497, Silent 146, Nonsense Mutation 43, Intron 35, 5'UTR 15, Frame Shift Del 14, Splice Site 13, 3'UTR 13, Splice Region 11, RNA 10, 5'Flank 7, Translation Start Site 2.

Variants (750 of 812; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TARDBP | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs80356733, CM081835; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 155/330 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 161/1194 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as rs200002683, COSV54050251; called by muse, mutect2, varscan2
- ABCB5 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709885; called by muse, mutect2
- AC024598.1 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); catalogued as COSV60823856; called by muse, mutect2, varscan2
- ACAN | c.4453G>C p.E1485Q | Missense Mutation (SNP) | VAF 22/653 reads (3%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.885); catalogued as COSV61365453; called by muse, mutect2
- ADAMTS16 | c.1984G>C p.G662R | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs745492958; called by muse, mutect2, varscan2
- ADARB2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV101186825; called by muse, varscan2
- ADGRD1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV55439703; called by muse, mutect2, varscan2
- ADGRL3 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 228/867 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV101547190; called by muse, mutect2, varscan2
- ADGRL3 | c.4450C>A p.P1484T (on ENST00000506720 / NM_001322402.2; = p.P1373T on NM_015236.6) | Missense Mutation (SNP) | VAF 164/753 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV101541133; called by muse, mutect2, varscan2
- AK7 | c.1161G>C p.L387F | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50869135; called by muse, mutect2
- ANK2 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 209/813 reads (26%) | catalogued as rs1445502811; called by muse, mutect2, varscan2
- ANKRD17 | c.6829C>G p.Q2277E | Missense Mutation (SNP) | VAF 85/735 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV58215958; called by muse, mutect2, varscan2
- ANKRD30BL | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs1312829980; called by muse, mutect2, varscan2
- ARHGEF4 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 94/549 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.33); catalogued as rs575658367; called by muse, mutect2, varscan2
- ASPHD1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs1041348374; called by muse, mutect2
- ATP10A | c.3631G>C p.A1211P | Missense Mutation (SNP) | VAF 172/700 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63517153, COSV63518435; called by muse, mutect2, varscan2
- ATP8B3 | c.3146T>C p.F1049S | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs1276710961; called by muse, mutect2, varscan2
- C1orf100 | c.239G>T p.C80F | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.63); catalogued as COSV57373570; called by muse, mutect2, varscan2
- C6 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 111/459 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as rs141740354; called by muse, mutect2, varscan2
- CAMTA1 | c.1967G>A p.S656N | Missense Mutation (SNP) | VAF 109/715 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as rs1403242862; called by muse, mutect2, varscan2
- CATSPER1 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 185/650 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56413791; called by muse, mutect2, varscan2
- CCDC85A | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.949); catalogued as COSV101339497; called by muse, mutect2, varscan2
- CCN5 | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 20/679 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99070746; called by muse, mutect2
- CCNYL1 | c.159G>T p.L53F | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs775777243; called by muse, mutect2
- CECR2 | c.3254G>T p.G1085V (on ENST00000342247 / NM_001290047.2; = p.G901V on NM_001290046.1) | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99376813; called by muse, mutect2, varscan2
- CENPF | c.2685C>A p.H895Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); catalogued as COSV100871765; called by muse, mutect2, varscan2
- CFHR5 | c.1142G>T p.C381F | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56830063; called by muse, mutect2, varscan2
- CLCN5 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV56585548; called by muse, mutect2, varscan2
- COG2 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1245232947; called by muse, mutect2
- COL1A2 | c.2296G>T p.G766C | Missense Mutation (SNP) | VAF 365/1080 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as CM070865; called by muse, mutect2, varscan2
- COL21A1 | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as rs552452598, COSV99056749; called by muse, mutect2, varscan2
- COL4A2 | c.4238del p.P1413Lfs*46 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs1189780729; called by mutect2, varscan2
- COL6A6 | c.4624C>A p.P1542T | Missense Mutation (SNP) | VAF 262/1392 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV62036720; called by mutect2, varscan2
- CP | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs374104537; called by muse, mutect2, varscan2
- CPAMD8 | c.4679A>G p.Q1560R (on ENST00000651564; = p.Q1513R on NM_015692.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1162923373; called by muse, mutect2, varscan2
- CSMD1 | c.2054G>C p.G685A (on ENST00000520002; = p.G684A on NM_033225.6) | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59327354; called by muse, varscan2
- CSMD1 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV101212095; called by mutect2, varscan2
- CSMD3 | c.9719C>A p.S3240Y (on ENST00000297405 / NM_001363185.1; = p.S3071Y on NM_052900.3) | Missense Mutation (SNP) | VAF 241/838 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as COSV52154582; called by muse, mutect2, varscan2
- CSMD3 | c.6730C>A p.Q2244K (on ENST00000297405 / NM_001363185.1; = p.Q2140K on NM_052900.3) | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV52276602, COSV99827125; called by muse, mutect2, varscan2
- CTF1 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs973838059; called by muse, mutect2, varscan2
- CTNND2 | c.2719C>G p.R907G | Missense Mutation (SNP) | VAF 110/821 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV58882411, COSV58909201, COSV58937843; called by muse, mutect2, varscan2
- DAAM2 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1320714530; called by muse, mutect2, varscan2
- DACH1 | c.2107C>T p.R703C (on ENST00000619232 / NM_001366712.1; = p.R449C on NM_004392.6) | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57498842; called by muse, mutect2, varscan2
- DCAF12L2 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV63581851, COSV63584283; called by muse, mutect2, varscan2
- DCAF12L2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1449903610, COSV63584148; called by muse, mutect2, varscan2
- DCAF4L2 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 276/1228 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs772779530; called by muse, mutect2, varscan2
- DIAPH2 | c.1067C>G p.S356* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as rs1338878948, COSV100233193; called by muse, mutect2, varscan2
- DMD | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV55856485, COSV55892843; called by muse, mutect2, varscan2
- DMXL1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 35/113 reads (31%) | catalogued as COSV100223586; called by muse, mutect2, varscan2
- DNAAF3 | c.607G>T p.D203Y (on ENST00000524407 / NM_001256715.2; = p.D250Y on NM_178837.4) | Missense Mutation (SNP) | VAF 162/536 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61276311; called by muse, mutect2, varscan2
- DNAH14 | c.4004A>G p.D1335G | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs146119353; called by muse, mutect2
- DNAH9 | c.9856C>T p.R3286C | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs990212558, COSV52342960; called by muse, mutect2, varscan2
- DOP1B | c.5340G>C p.E1780D | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.13); catalogued as COSV67692799; called by muse, mutect2, varscan2
- DPP4 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs955700842; called by muse, mutect2, varscan2
- DYSF | c.1481-1G>C p.X494_splice | Splice Site (SNP) | VAF 153/474 reads (32%) | catalogued as CS103818; called by muse, mutect2, varscan2
- EML2 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV55597505; called by muse, mutect2
- ENPP1 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 109/489 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100719477; called by muse, mutect2, varscan2
- EP400 | c.9256G>T p.A3086S | Missense Mutation (SNP) | VAF 115/635 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.041); catalogued as rs758067951; called by muse, mutect2, varscan2
- ERBB3 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 134/686 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV57264899; called by muse, mutect2, varscan2
- FAM186A | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as COSV59246073; called by muse, mutect2, varscan2
- FASTKD3 | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755486080; called by muse, mutect2, varscan2
- FCRL1 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.714); catalogued as COSV63824711; called by muse, mutect2, varscan2
- FLNC | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as rs751963297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRYL | c.123G>A p.E41= | Splice Region (SNP) | VAF 14/202 reads (7%) | catalogued as rs771078204; called by muse, mutect2
- FSIP2 | c.18109G>C p.E6037Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV58090660; called by muse, mutect2, varscan2
- FXR2 | c.832-1G>C p.X278_splice | Splice Site (SNP) | VAF 91/406 reads (22%) | catalogued as COSV51468219; called by muse, mutect2, varscan2
- FZD4 | c.1065del p.A356Qfs*2 | Frame Shift Del (DEL) | VAF 158/995 reads (16%) | catalogued as COSV72294771; called by mutect2, pindel, varscan2
- GABRA2 | c.1059+5G>T | Splice Region (SNP) | VAF 83/269 reads (31%) | catalogued as COSV100734787; called by muse, mutect2, varscan2
- GABRR1 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65620424; called by muse, mutect2
- GIPC2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 37/847 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.616); catalogued as COSV54574357; called by muse, mutect2
- GOLGA6L7 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 123/449 reads (27%) | catalogued as rs747558475, COSV101629691; called by muse, mutect2, varscan2
- GPAT3 | c.402C>G p.F134L | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs746642807, COSV52358311; called by muse, mutect2, varscan2
- GPR152 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 94/577 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56888458; called by muse, mutect2, varscan2
- GUCY1A2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV56506377; called by muse, mutect2, varscan2
- H2AC16 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV58901212; called by muse, mutect2
- HCN1 | c.1404A>T p.K468N | Missense Mutation (SNP) | VAF 57/427 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV57498110; called by muse, mutect2, varscan2
- HELZ2 | c.5531C>T p.A1844V (on ENST00000467148 / NM_001037335.2; = p.A1275V on NM_033405.3) | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as rs766203366; called by muse, mutect2, varscan2
- HOXA1 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 287/767 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs768113272; called by muse, mutect2, varscan2
- HP | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1319691462; called by muse, mutect2, varscan2
- HTR2C | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as COSV52209650; called by muse, mutect2, varscan2
- IBTK | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774671938; called by muse, mutect2, varscan2
- IFI44 | c.1290G>T p.G430= | Splice Region (SNP) | VAF 40/124 reads (32%) | catalogued as rs1232028217; called by muse, mutect2, varscan2
- IFT80 | c.2100G>T p.R700S | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58448958; called by muse, mutect2, varscan2
- IGHV3-23 | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 173/1236 reads (14%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.024); catalogued as rs554563473; called by muse, mutect2, varscan2
- IGLV2-14 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 110/781 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as rs369136397; called by muse, mutect2, varscan2
- IP6K2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 75/365 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV60795474; called by muse, mutect2, varscan2
- IQCA1 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs1224299772, COSV54502405; called by muse, mutect2, varscan2
- ITGA9 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53250607; called by muse, mutect2, varscan2
- ITK | c.1765C>A p.Q589K | Missense Mutation (SNP) | VAF 39/650 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101439907; called by muse, mutect2
- KIAA1109 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52692828; called by muse, mutect2, varscan2
- LCORL | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs745879765; called by muse, mutect2, varscan2
- LRP2 | c.10467C>A p.F3489L | Missense Mutation (SNP) | VAF 146/886 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV55560260; called by muse, mutect2, varscan2
- MAGEL2 | c.3498C>G p.Y1166* | Nonsense Mutation (SNP) | VAF 88/281 reads (31%) | catalogued as COSV58565955; called by muse, mutect2, varscan2
- MAGI1 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as rs770405336; called by muse, mutect2, varscan2
- MAGI2 | c.4274G>T p.R1425L | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); catalogued as rs1053239653; called by muse, mutect2, varscan2
- MATN1 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 94/537 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV65650786; called by muse, mutect2, varscan2
- METTL17 | c.290G>C p.R97T | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228255; called by muse, mutect2, varscan2
- METTL2A | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 8/165 reads (5%) | catalogued as rs1199680194; called by muse, mutect2
- MGA | c.3332A>G p.Y1111C | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1170625407; called by muse, mutect2, varscan2
- MGAM | c.3211C>T p.P1071S | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV101527688; called by muse, mutect2, varscan2
- MICAL3 | c.2740C>G p.Q914E | Missense Mutation (SNP) | VAF 94/532 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); catalogued as rs929964344; called by muse, mutect2, varscan2
- MPL | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 127/621 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100991414; called by muse, mutect2, varscan2
- MTHFD1L | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 184/478 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs552389460, COSV100945128; called by muse, mutect2, varscan2
- MTOR | c.6586G>A p.E2196K | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63870516; called by muse, mutect2, varscan2
- MUC12 | c.9224C>G p.S3075* (on ENST00000379442; = p.S2932* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 149/4234 reads (4%) | catalogued as rs766843944; called by muse, mutect2
- MYH8 | c.1768del p.D590Tfs*15 | Frame Shift Del (DEL) | VAF 112/619 reads (18%) | catalogued as COSV67973639; called by mutect2, pindel, varscan2
- MYO16 | c.3875C>A p.P1292Q | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100696764; called by muse, mutect2, varscan2
- NEB | c.10476A>C p.E3492D | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV51437629; called by muse, mutect2, varscan2
- NLRP14 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100205020; called by muse, mutect2, varscan2
- NOSTRIN | c.886G>C p.E296Q (on ENST00000317647 / NM_001039724.4; = p.E218Q on NM_052946.3) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV58323472; called by muse, mutect2, varscan2
- NOTCH1 | c.345del p.T116Pfs*7 | Frame Shift Del (DEL) | VAF 322/716 reads (45%) | catalogued as COSV53075400; called by mutect2, pindel, varscan2
- NRP2 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 150/689 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1186838471, COSV55935827; called by muse, mutect2, varscan2
- NUP107 | c.1783C>A p.H595N | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.415); catalogued as rs1490207049, COSV104392039; called by muse, mutect2, varscan2
- NUP98 | c.4538G>T p.R1513L (on ENST00000359171 / NM_001365126.1; = p.R1496L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV61430789; called by muse, mutect2, varscan2
- NUTF2 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs767988860; called by muse, mutect2, varscan2
- OR10A2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 155/377 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368357397; called by muse, mutect2, varscan2
- OR11L1 | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 173/557 reads (31%) | catalogued as COSV63313687; called by muse, mutect2, varscan2
- OR2T2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 206/1553 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs761735642; called by muse, mutect2, varscan2
- OR4K1 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV53461107, COSV53461444; called by muse, mutect2, varscan2
- OR52E2 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV58612397; called by muse, mutect2, varscan2
- OR5D14 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1486007798; called by muse, mutect2, varscan2
- OR8J1 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1453714130; called by muse, mutect2, varscan2
- OTOGL | c.2513C>T p.S838F (on ENST00000547103; = p.S829F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs1193170579; called by muse, mutect2, varscan2
- PCDHGB3 | c.1627A>T p.S543C | Missense Mutation (SNP) | VAF 334/706 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV53953709; called by muse, mutect2, varscan2
- PCYOX1 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs565888631; called by muse, mutect2, varscan2
- PES1 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 125/510 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs1374386521; called by muse, mutect2, varscan2
- PFKL | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 86/112 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs746385697, COSV100826965; called by muse, mutect2, varscan2
- PGRMC2 | c.78G>C p.E26D | Missense Mutation (SNP) | VAF 237/881 reads (27%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.077); catalogued as COSV56480893; called by muse, mutect2, varscan2
- PHC2 | c.1628C>G p.S543C (on ENST00000257118 / NM_198040.2; = p.S8C on NM_004427.4) | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV57103918; called by muse, mutect2
- PHLPP1 | c.821del p.P274Rfs*79 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs1366242347; called by mutect2, pindel, varscan2
- PKD1L3 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV58663321; called by muse, mutect2, varscan2
- PKD2 | c.2050T>G p.Y684D | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CD025952; called by muse, mutect2, varscan2
- PKHD1L1 | c.3809C>A p.T1270K | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV65744747; called by muse, mutect2, varscan2
- PLAUR | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 75/510 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs751012764, COSV99654986; called by muse, mutect2, varscan2
- PLEKHN1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 84/515 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370128139; called by muse, mutect2, varscan2
- PLXNA1 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 122/472 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754208943; called by muse, mutect2, varscan2
- POLD1 | c.1799C>T p.T600I | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1060501810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMGNT1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 147/1002 reads (15%) | PolyPhen possibly damaging (0.687); catalogued as rs527454065, COSV64340293; called by muse, mutect2, varscan2
- POTEE | c.200A>T p.H67L | Missense Mutation (SNP) | VAF 588/1717 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as rs777410341, COSV100389092; called by muse, mutect2, varscan2
- PPFIA2 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as rs768985652; called by muse, mutect2, varscan2
- PPP2R1B | c.397C>G p.P133A | Missense Mutation (SNP) | VAF 94/764 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs138745640; called by muse, mutect2, varscan2
- PRDM9 | c.1783C>T p.L595F | Missense Mutation (SNP) | VAF 178/1120 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1229339001; called by muse, varscan2
- PROK1 | c.83G>C p.R28P | Missense Mutation (SNP) | VAF 298/632 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV99602705; called by muse, mutect2, varscan2
- PROZ | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 175/452 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760090528; called by muse, mutect2, varscan2
- PRR23B | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV61493461, COSV61494304; called by muse, mutect2, varscan2
- RAD54L2 | c.3805C>T p.R1269C | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs760576553; called by muse, mutect2, varscan2
- RANBP2 | c.4187C>T p.T1396I | Missense Mutation (SNP) | VAF 192/599 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99313200; called by muse, mutect2, varscan2
- RAPGEF4 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.144); catalogued as rs200419099, COSV51390309; called by muse, mutect2, varscan2
- RC3H1 | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 181/727 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51219401; called by muse, mutect2, varscan2
- RGSL1 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1208908209; called by muse, mutect2
- RIMS2 | c.4609G>T p.G1537* (on ENST00000666250 / NM_001348490.2; = p.G1108* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 139/424 reads (33%) | catalogued as COSV51706738; called by muse, mutect2, varscan2
- RNF213 | c.13795C>T p.Q4599* | Nonsense Mutation (SNP) | VAF 264/585 reads (45%) | catalogued as rs1235347045; called by muse, mutect2, varscan2
- RNPEP | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759183101; called by muse, mutect2, varscan2
- RP1 | c.3712G>T p.G1238C | Missense Mutation (SNP) | VAF 139/608 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV55120789; called by muse, mutect2, varscan2
- RPGRIP1 | c.3766C>G p.L1256V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs1405508889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUFY3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as rs748059452, COSV56915316; called by muse, mutect2
- RYR2 | c.4706G>T p.G1569V | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1455659868; called by muse, mutect2, varscan2
- RYR2 | c.8945T>C p.F2982S | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63688641; called by muse, mutect2, varscan2
- SASH1 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460340570, COSV66559266; called by muse, mutect2, varscan2
- SCARF2 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1453251462; called by muse, mutect2, varscan2
- SDK1 | c.4010C>A p.S1337* | Nonsense Mutation (SNP) | VAF 130/714 reads (18%) | catalogued as COSV67365196; called by muse, mutect2, varscan2
- SLC17A6 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 395/868 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54138198; called by muse, mutect2, varscan2
- SLC35A5 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | catalogued as COSV99656811; called by muse, mutect2
- SLC7A3 | c.1193C>A p.A398E | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53226599; called by muse, mutect2, varscan2
- SMAD1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 70/407 reads (17%) | catalogued as COSV57472535; called by mutect2, varscan2
- SMYD1 | c.771C>A p.N257K | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs372144239, COSV70225655; called by muse, mutect2, varscan2
- SPHKAP | c.4284G>C p.L1428F | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100763879; called by muse, mutect2, varscan2
- SPOCD1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.697); catalogued as rs754757581; called by muse, mutect2, varscan2
- SRRM2 | c.5116A>G p.R1706G | Missense Mutation (SNP) | VAF 165/601 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1483817314; called by muse, mutect2, varscan2
- SRRT | c.2255A>G p.N752S | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as rs1244991277; called by muse, mutect2, varscan2
- SYNJ1 | c.2070G>A p.R690= | Splice Region (SNP) | VAF 16/159 reads (10%) | catalogued as rs768565296; called by muse, mutect2
- TCAF1 | c.484del p.E162Rfs*14 | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | catalogued as rs1562961320; called by mutect2, pindel, varscan2
- TEDDM1 | c.476T>C p.M159T | Missense Mutation (SNP) | VAF 203/767 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs1341499028; called by muse, mutect2, varscan2
- TGFB1I1 | c.59G>T p.R20M (on ENST00000394863 / NM_001042454.3; = p.R3M on NM_015927.4) | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs138308548; called by muse, mutect2, varscan2
- TMEM176A | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV50240646; called by muse, mutect2, varscan2
- TNRC6A | c.4721A>G p.Y1574C | Missense Mutation (SNP) | VAF 94/459 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747762007, COSV59368177; called by muse, mutect2, varscan2
- TNS4 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs951474065; called by muse, mutect2, varscan2
- TOP3B | c.2054A>T p.Y685F | Missense Mutation (SNP) | VAF 108/560 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV64119122; called by muse, mutect2, varscan2
- TSHZ2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.796); catalogued as COSV61589520; called by muse, mutect2, varscan2
- TTN | c.4610G>T p.G1537V (on ENST00000591111; = p.G1491V on NM_003319.4) | Missense Mutation (SNP) | VAF 25/202 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV59863273; called by muse, mutect2, varscan2
- TTN | c.4609G>T p.G1537C (on ENST00000591111; = p.G1491C on NM_003319.4) | Missense Mutation (SNP) | VAF 25/201 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV99045874; called by muse, mutect2, varscan2
- TUBB8 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 287/698 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59114472; called by muse, varscan2
- TULP3 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137879043, COSV68118176; called by muse, mutect2, varscan2
- UBA3 | c.63-1G>A p.X21_splice | Splice Site (SNP) | VAF 47/302 reads (16%) | catalogued as rs111316801; called by muse, mutect2, varscan2
- UNC79 | c.3316del p.A1106Qfs*13 (on ENST00000393151 / NM_001346218.2; = p.A929Qfs*13 on NM_020818.5) | Frame Shift Del (DEL) | VAF 151/480 reads (31%) | catalogued as COSV99828131; called by mutect2, pindel, varscan2
- UTP20 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.084); catalogued as rs771327304; called by muse, varscan2
- UTRN | c.8755G>C p.E2919Q | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs372933420, COSV62311795, COSV62313992; called by muse, mutect2, varscan2
- VIM | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 176/491 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as rs569704234; called by muse, mutect2, varscan2
- VPS13B | c.9312G>C p.Q3104H | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100662099; called by muse, mutect2, varscan2
- VWA3B | c.3390C>G p.F1130L | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV101289424; called by muse, mutect2
- ZDBF2 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 114/292 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs751321970; called by muse, mutect2, varscan2
- ZFHX4 | c.9732G>T p.Q3244H | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51480195; called by muse, mutect2, varscan2
- ZFPM2 | c.2220G>C p.K740N | Missense Mutation (SNP) | VAF 153/1281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1346893995; called by muse, mutect2, varscan2
- ZIM2 | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV55635971; called by muse, mutect2, varscan2
- ZMYND8 | c.1138G>A p.D380N (on ENST00000311275 / NM_001363741.2; = p.D400N on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1424695810, COSV53691127; called by muse, mutect2, varscan2
- ZNF236 | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.056); catalogued as COSV99471478; called by muse, mutect2, varscan2
- ABCB8 | c.946C>A p.L316I (on ENST00000297504 / NM_001282291.2; = p.L299I on NM_007188.5) | Missense Mutation (SNP) | VAF 67/424 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC11 | c.1168T>A p.L390M | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ABCC12 | c.582G>C p.L194F | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ABCD2 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ABCG8 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 112/767 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ABHD12B | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- AC011455.2 | c.1497G>C p.Q499H | Missense Mutation (SNP) | VAF 71/482 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- AC011455.2 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 207/1528 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC090517.4 | c.1567A>T p.S523C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AC100868.1 | c.703A>T p.I235F | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ACSM4 | c.862T>G p.C288G | Missense Mutation (SNP) | VAF 177/576 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGB | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AFP | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AHI1 | c.564G>C p.L188F | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- AKAP13 | c.4334A>G p.H1445R | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKT1S1 | c.683G>C p.R228P (on ENST00000344175 / NM_001098633.4; = p.R248P on NM_032375.5) | Missense Mutation (SNP) | VAF 65/628 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ALDH1L1 | c.1102T>A p.C368S | Missense Mutation (SNP) | VAF 105/421 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ALG9 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 182/749 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ALKBH7 | c.502A>T p.R168W | Missense Mutation (SNP) | VAF 173/432 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALS2CL | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANAPC5 | c.1887del p.F629Lfs*13 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- ANK2 | c.4914C>G p.N1638K | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.10617G>C p.W3539C | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD33B | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 39/193 reads (20%) | called by muse, mutect2, varscan2
- ANKRD53 | c.1312A>T p.T438S | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD61 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 117/691 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ANO8 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- APAF1 | c.3487_3491del p.H1163Vfs*18 (on ENST00000551964 / NM_181861.2; = p.H1109Vfs*18 on NM_001160.3) | Frame Shift Del (DEL) | VAF 63/395 reads (16%) | called by mutect2, pindel, varscan2
- AQR | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 94/431 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ARHGAP23 | c.2678A>C p.K893T | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ARHGAP31 | c.2941G>C p.E981Q | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF2 | c.1231G>T p.E411* (on ENST00000361247 / NM_001162383.2; = p.E383* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/228 reads (14%) | called by muse, varscan2
- ARHGEF25 | c.536T>C p.L179S | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF4 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ARID3B | c.1615C>T p.H539Y (on ENST00000622429 / NM_001307939.1; = p.H538Y on NM_006465.4) | Missense Mutation (SNP) | VAF 41/414 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ARID5B | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 173/790 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC4 | c.2129T>A p.V710D | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASB5 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 52/436 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ATRIP | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 130/558 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- B3GALT1 | c.690T>G p.S230R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- BDKRB1 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- BDKRB2 | c.796A>T p.R266W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- BHLHE22 | c.835A>C p.K279Q | Missense Mutation (SNP) | VAF 345/1416 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRCA1 | c.3484G>C p.D1162H | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C10orf71 | c.2246C>T p.T749I | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- C10orf99 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 148/350 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- C2CD2L | c.1933A>G p.T645A | Missense Mutation (SNP) | VAF 153/469 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- C8orf76 | c.915C>G p.S305R | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CACNA1D | c.4909A>G p.T1637A (on ENST00000350061 / NM_001128840.3; = p.T1657A on NM_000720.4) | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALCRL | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CASP1 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 180/818 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CATSPERG | c.2656A>C p.K886Q | Missense Mutation (SNP) | VAF 147/451 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CBLN1 | c.553T>A p.F185I | Missense Mutation (SNP) | VAF 93/435 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CC2D2A | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 27/804 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- CCDC110 | c.2146C>G p.Q716E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCDC168 | c.14762A>T p.H4921L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CCDC178 | c.2489C>A p.S830Y (on ENST00000383096 / NM_001105528.3; = p.S792Y on NM_198995.3) | Missense Mutation (SNP) | VAF 91/453 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD9 | c.653G>T p.C218F | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH20 | c.413A>T p.D138V | Missense Mutation (SNP) | VAF 151/420 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDH24 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CEP63 | c.1456G>C p.G486R | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- CERS6 | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 96/682 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CFHR5 | c.1143C>A p.C381* | Nonsense Mutation (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- CHD5 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD9 | c.4429A>C p.K1477Q | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CHD9 | c.4837G>T p.D1613Y | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CHGB | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRDL1 | c.985T>A p.F329I (on ENST00000372045; = p.F335I on NM_145234.4) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CHST13 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CIAO1 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 78/482 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNMD | c.463A>C p.K155Q | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNR1 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 239/726 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CNTNAP2 | c.3838G>A p.V1280I | Missense Mutation (SNP) | VAF 129/668 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- COL5A1 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 412/740 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COL6A5 | c.5140C>T p.L1714F | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- COL9A2 | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 133/782 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- COPG1 | c.582C>A p.Y194* | Nonsense Mutation (SNP) | VAF 56/444 reads (13%) | called by muse, mutect2
- CRACDL | c.2623G>T p.D875Y | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREB3L4 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CRISP1 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CRYBG3 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CSMD3 | c.3509T>C p.F1170S (on ENST00000297405 / NM_001363185.1; = p.F1066S on NM_052900.3) | Missense Mutation (SNP) | VAF 59/584 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTDP1 | c.1454A>C p.Q485P | Missense Mutation (SNP) | VAF 139/364 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CTDSPL2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- CUX2 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CYP11B1 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 389/1855 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP7A1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 289/1506 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- DCAF8L1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DCLK2 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDHD1 | c.1937G>T p.W646L (on ENST00000323669; = p.W843L on NM_030637.3) | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGCR8 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 75/344 reads (22%) | called by muse, mutect2, varscan2
- DGKZ | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 83/625 reads (13%) | called by muse, mutect2, varscan2
- DNAAF4 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- DNAH2 | c.8151G>T p.E2717D | Missense Mutation (SNP) | VAF 149/300 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- DNAH3 | c.11180A>T p.Y3727F | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DNAH5 | c.3965C>T p.S1322L | Missense Mutation (SNP) | VAF 136/802 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.2593T>A p.Y865N | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- DNAH9 | c.5725T>G p.Y1909D | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAJC19 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 417/1467 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DTD2 | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYNC2H1 | c.10812+1G>T p.X3604_splice | Splice Site (SNP) | VAF 61/248 reads (25%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EHBP1L1 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF5B | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ELOA2 | c.1972C>A p.Q658K | Missense Mutation (SNP) | VAF 67/482 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- EMCN | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EMILIN3 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENOPH1 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ENPP1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 109/490 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- ENPP1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 54/225 reads (24%) | called by muse, mutect2, varscan2
- ENPP2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- EPPK1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- EPRS1 | c.1205G>C p.R402T | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ETNPPL | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXOC5 | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EYA1 | c.1200-3T>A | Splice Region (SNP) | VAF 162/771 reads (21%) | called by muse, mutect2, varscan2
- EYS | c.332T>A p.F111Y | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- F2 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 145/788 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM120C | c.3246A>T p.L1082F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.015); called by muse, mutect2
- FAM149A | c.1205A>T p.Y402F (on ENST00000356371 / NM_001367768.2; = p.Y111F on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/430 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FAM171B | c.2283G>T p.R761S | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FAM217B | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 33/175 reads (19%) | called by muse, mutect2, varscan2
- FAM47A | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAT4 | c.8185A>G p.S2729G | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FBXL6 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL1 | c.886+1G>T p.X296_splice | Splice Site (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- FCSK | c.2157G>T p.G719= | Splice Region (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- FGD6 | c.952A>G p.R318G | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FGF3 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 157/742 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FHL5 | c.549T>A p.H183Q | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FLT1 | c.2695A>C p.T899P | Missense Mutation (SNP) | VAF 167/805 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC3A | c.3043G>C p.E1015Q (on ENST00000492622 / NM_001079673.2; = p.E959Q on NM_014923.5) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FOXD4 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 42/1078 reads (4%) | called by muse, mutect2
- FOXP2 | c.2072C>G p.T691R | Missense Mutation (SNP) | VAF 103/291 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FRS3 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRY | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 53/323 reads (16%) | called by muse, mutect2, varscan2
- FUT10 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- GALK2 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- GALNT17 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 106/567 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GALNT2 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 124/417 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GAS2L3 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 56/373 reads (15%) | called by muse, mutect2, varscan2
- GNPAT | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 149/643 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GOLGA6L22 | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 134/726 reads (18%) | SIFT tolerated (0.17); called by muse, mutect2, varscan2
- GOLGA8H | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 125/1288 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GOLGA8S | c.1774A>T p.T592S | Missense Mutation (SNP) | VAF 432/1838 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- GPAA1 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 106/577 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- GPAM | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPLD1 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- GPR161 | c.1204+3A>C | Splice Region (SNP) | VAF 95/304 reads (31%) | called by muse, mutect2, varscan2
- GPX5 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GRIN2B | c.3193A>T p.T1065S | Missense Mutation (SNP) | VAF 158/905 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GYG1 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.063); called by muse, mutect2
- H2AC1 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 86/364 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- H4C6 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 79/440 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- HAGHL | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 89/435 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- HAS1 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HECTD1 | c.4814C>T p.T1605I | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HECTD1 | c.3962C>T p.S1321F | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HEPHL1 | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 362/1046 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HMCN1 | c.15817A>T p.I5273F | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- HOXD1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 157/476 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HSPA4L | c.1018A>C p.I340L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- HSPG2 | c.13150G>A p.A4384T | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HTR2A | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTT | c.4693G>C p.E1565Q | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- IGF2BP2 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 128/414 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- IGF2R | c.5003_5009del p.H1668Lfs*29 | Frame Shift Del (DEL) | VAF 121/423 reads (29%) | called by mutect2, pindel, varscan2
- IGHMBP2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- IGKV2D-28 | c.345del p.A116Lfs*? | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | called by mutect2, varscan2
- IL31 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 123/431 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IMPG2 | c.2421G>C p.R807S | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IPO9 | c.970+1G>T p.X324_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- IQCD | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 153/446 reads (34%) | called by muse, mutect2, varscan2
- IQGAP2 | c.3739G>A p.V1247M | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ITPKB | c.2119G>T p.V707L | Missense Mutation (SNP) | VAF 322/993 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KANK4 | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 140/624 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KCNK15 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- KCTD3 | c.2399C>G p.S800C | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KDM5D | c.4046A>T p.N1349I | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- KDM5D | c.1213-1G>T p.X405_splice | Splice Site (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- KIF21B | c.4278G>T p.M1426I (on ENST00000422435 / NM_001252100.2; = p.M1413I on NM_017596.4) | Missense Mutation (SNP) | VAF 102/353 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR2DL4 | c.873C>G p.I291M (on ENST00000396284; = p.I252M on NM_001080772.2) | Missense Mutation (SNP) | VAF 159/643 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- KIR3DL1 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 191/610 reads (31%) | called by muse, mutect2, varscan2
- KLF14 | c.396del p.S133Pfs*39 | Frame Shift Del (DEL) | VAF 36/196 reads (18%) | called by mutect2, pindel, varscan2
- KLHDC3 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 149/870 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KLHL33 | c.1335G>T p.W445C | Missense Mutation (SNP) | VAF 126/371 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLKB1 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 164/620 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KREMEN1 | c.282G>A p.W94* (on ENST00000407188; = p.W96* on NM_032045.5) | Nonsense Mutation (SNP) | VAF 154/543 reads (28%) | called by muse, mutect2, varscan2
- LAMA5 | c.7550G>T p.R2517M | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- LAMC3 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 68/424 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LCMT2 | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 159/366 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEKR1 | c.498G>T p.W166C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- LEKR1 | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LHFPL3 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 147/391 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LILRB2 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 151/609 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIN7B | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 82/612 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRIT3 | c.1614A>T p.Q538H | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- LRRC8B | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC2 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MALRD1 | c.2389C>A p.L797M | Missense Mutation (SNP) | VAF 119/320 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MAP7D3 | c.704C>A p.T235N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by mutect2, varscan2
- MARF1 | c.4635G>C p.W1545C | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MARK3 | c.712A>C p.S238R | Missense Mutation (SNP) | VAF 282/659 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDGA2 | c.1700G>T p.G567V (on ENST00000399232 / NM_001113498.2; = p.G269V on NM_182830.4) | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MDGA2 | c.1699G>T p.G567* (on ENST00000399232 / NM_001113498.2; = p.G269* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- MDN1 | c.15628G>C p.E5210Q | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MEGF10 | c.3002G>C p.S1001T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MGAM2 | c.6232G>T p.V2078F | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated, low confidence (0.3); called by muse, mutect2, varscan2
- MIER1 | c.295G>T p.E99* (on ENST00000355356 / NM_001077701.3; = p.E116* on NM_020948.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- MKI67 | c.4276G>C p.G1426R | Missense Mutation (SNP) | VAF 273/662 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MPP3 | c.1476G>T p.R492S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- MTUS2 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC2 | c.3979G>A p.D1327N | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUL1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 81/526 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MVP | c.497C>G p.T166S | Missense Mutation (SNP) | VAF 254/785 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MYH13 | c.3575C>T p.T1192I | Missense Mutation (SNP) | VAF 414/875 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- MYLK | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 248/915 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MYO16 | c.3874C>A p.P1292T | Missense Mutation (SNP) | VAF 127/355 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO7A | c.4799G>A p.G1600E | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO9A | c.6029C>G p.P2010R | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MYPN | c.3325A>T p.N1109Y | Missense Mutation (SNP) | VAF 399/803 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA16 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- NBPF15 | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 87/613 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- NCKAP5 | c.4378G>A p.D1460N | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NDNF | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NETO2 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NGRN | c.552C>G p.D184E | Missense Mutation (SNP) | VAF 89/601 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NKAPD1 | c.866C>G p.S289* (on ENST00000280352 / NM_001082970.2; = p.S290* on NM_018195.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- NOTCH3 | c.4368C>G p.F1456L | Missense Mutation (SNP) | VAF 126/596 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NOX4 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); called by muse, varscan2
- NOX4 | c.1218-1G>C p.X406_splice | Splice Site (SNP) | VAF 22/90 reads (24%) | called by muse, varscan2
- NPIPB15 | c.67-1G>T p.X23_splice | Splice Site (SNP) | VAF 95/781 reads (12%) | called by muse, mutect2, varscan2
- NPY1R | c.548C>G p.P183R | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NRXN1 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSMCE1 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- NSUN2 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUGGC | c.1859G>C p.R620T | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- OR2C3 | c.557T>A p.M186K | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR4C12 | c.601A>T p.S201C | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR6Q1 | c.779T>C p.F260S | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- OR8A1 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 65/445 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- OR8B4 | c.396G>T p.M132I | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8D2 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8H2 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 112/387 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OTOA | c.1225G>A p.V409I (on ENST00000286149; = p.V395I on NM_144672.4) | Missense Mutation (SNP) | VAF 171/1078 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OXR1 | c.1414G>T p.G472W (on ENST00000442977 / NM_001198532.1; = p.G471W on NM_018002.3) | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- P2RY14 | c.780G>C p.Q260H | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- PARN | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 70/620 reads (11%) | called by muse, mutect2, varscan2
- PAX1 | c.1360C>G p.P454A | Missense Mutation (SNP) | VAF 84/685 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PCDHGA3 | c.2415C>A p.N805K | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGC3 | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 15/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCNX1 | c.1276A>T p.K426* | Nonsense Mutation (SNP) | VAF 79/217 reads (36%) | called by muse, mutect2, varscan2
- PCSK7 | c.2060A>T p.Y687F | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.062); called by muse, varscan2
- PDGFC | c.960G>C p.L320F | Missense Mutation (SNP) | VAF 61/473 reads (13%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX10 | c.103A>T p.S35C | Missense Mutation (SNP) | VAF 74/409 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PHLDB2 | c.1046G>T p.C349F | Missense Mutation (SNP) | VAF 124/482 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by mutect2, varscan2
- PLEKHH2 | c.3868C>G p.Q1290E | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- PLPPR3 | c.1441C>G p.R481G (on ENST00000520876 / NM_001270366.2; = p.R509G on NM_024888.2) | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLXNA2 | c.3835G>C p.D1279H | Missense Mutation (SNP) | VAF 94/677 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLQ | c.2618G>T p.R873M | Missense Mutation (SNP) | VAF 104/544 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- POLR2I | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 221/934 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- POM121 | c.1423G>C p.E475Q (on ENST00000434423; = p.E210Q on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- POTEH | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 47/1009 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- PPL | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 30/835 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- PPP1R13L | c.2004C>G p.I668M | Missense Mutation (SNP) | VAF 72/502 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PPP2R3B | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 112/471 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PPP2R3B | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 87/422 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP4R1 | c.2064C>G p.H688Q (on ENST00000400556 / NM_001042388.3; = p.H671Q on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PREX2 | c.213+2T>C p.X71_splice | Splice Site (SNP) | VAF 60/298 reads (20%) | called by muse, mutect2, varscan2
- PRRC2A | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 46/221 reads (21%) | called by muse, mutect2, varscan2
- PRRT4 | c.2610G>T p.Q870H | Missense Mutation (SNP) | VAF 132/772 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- PRTG | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- PTPN13 | c.4064C>A p.T1355N (on ENST00000411767 / NM_080683.3; = p.T1336N on NM_006264.3) | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PTPN2 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTPRO | c.1238A>G p.Q413R | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS22 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.08); called by muse, mutect2
- RIMS2 | c.4610G>T p.G1537V (on ENST00000666250 / NM_001348490.2; = p.G1108V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/432 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF168 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RNF40 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 26/862 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RP1 | c.3100C>T p.H1034Y | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPF2 | c.585_586dup p.R196Lfs*8 | Frame Shift Ins (INS) | VAF 47/271 reads (17%) | called by mutect2, pindel, varscan2
- RPL28 | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 92/656 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRM1 | c.464A>T p.Y155F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RSPO1 | c.533G>T p.R178M | Missense Mutation (SNP) | VAF 130/715 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RTL9 | c.391T>C p.S131P | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.3619C>A p.L1207I | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SARAF | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SCARA3 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SCLT1 | c.117A>T p.Q39H | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SCN10A | c.3924G>C p.W1308C | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SCN7A | c.649A>T p.I217F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEL1L | c.1860G>T p.R620S | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SIAH1 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 88/467 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SKOR2 | c.1333G>T p.A445S | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- SLC26A1 | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A5 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 199/1273 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SLC2A3 | c.1447A>C p.M483L | Missense Mutation (SNP) | VAF 143/898 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, varscan2
- SLC4A4 | c.374G>T p.W125L (on ENST00000264485 / NM_001098484.3; = p.W81L on NM_003759.4) | Missense Mutation (SNP) | VAF 205/630 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A4 | c.1472T>C p.L491P (on ENST00000264485 / NM_001098484.3; = p.L447P on NM_003759.4) | Missense Mutation (SNP) | VAF 68/512 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A18 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC7A1 | c.1739A>C p.Q580P | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A6 | c.795-1G>C p.X265_splice | Splice Site (SNP) | VAF 43/303 reads (14%) | called by muse, mutect2, varscan2
- SNAP91 | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOHLH1 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 287/502 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA31A1 | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 469/1294 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SPATA31A3 | c.3432G>T p.Q1144H | Missense Mutation (SNP) | VAF 169/540 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SPATA31D1 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 219/551 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SPICE1 | c.487C>G p.P163A | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SPTBN4 | c.5677C>A p.Q1893K | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- STIP1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 64/308 reads (21%) | called by muse, mutect2, varscan2
- STMND1 | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SUMF2 | c.206G>T p.G69V (on ENST00000652303; = p.G50V on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/486 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SYT10 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYT13 | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 312/730 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TACC2 | c.4856C>G p.A1619G | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TAF1L | c.3854C>A p.A1285E | Missense Mutation (SNP) | VAF 132/345 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF4 | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 183/454 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TANC1 | c.2515G>T p.G839W | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TARS3 | c.1119G>T p.L373F | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D8 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 69/727 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- TCIRG1 | c.2281G>T p.G761C | Missense Mutation (SNP) | VAF 153/736 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- TDRD6 | c.3488A>G p.D1163G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TECRL | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- TENM3 | c.1103G>C p.G368A | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TFAP2E | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- THEM5 | c.404C>A p.P135Q | Missense Mutation (SNP) | VAF 97/417 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- THSD7B | c.1738G>T p.G580W | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- TMEM108 | c.1214T>G p.V405G | Missense Mutation (SNP) | VAF 117/471 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM117 | c.1276A>G p.N426D | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- TMEM243 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2
- TNN | c.2500G>T p.A834S | Missense Mutation (SNP) | VAF 274/826 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TPCN1 | c.2419G>C p.G807R | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TPD52 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 965/1913 reads (50%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TPD52L2 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- TPRA1 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRDN | c.2125G>T p.A709S | Missense Mutation (SNP) | VAF 77/374 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- TREM2 | c.41-1G>A p.X14_splice | Splice Site (SNP) | VAF 60/501 reads (12%) | called by muse, mutect2, varscan2
- TRIM32 | c.1929C>A p.Y643* | Nonsense Mutation (SNP) | VAF 96/166 reads (58%) | called by muse, mutect2, varscan2
- TSGA10 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTC19 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TTLL5 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 62/386 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.79202G>A p.G26401E (on ENST00000591111; = p.G18977E on NM_003319.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.78863del p.G26288Efs*8 (on ENST00000591111; = p.G18864Efs*8 on NM_003319.4) | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- TTN | c.52505C>A p.A17502D (on ENST00000591111; = p.A10078D on NM_003319.4) | Missense Mutation (SNP) | VAF 137/837 reads (16%) | PolyPhen benign (0.369); called by muse, mutect2, varscan2
- TTN | c.39130G>T p.E13044* (on ENST00000591111; = p.E5620* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.25907C>A p.P8636H (on ENST00000591111; = p.P7709H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/150 reads (28%) | PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TUBB8P7 | n.703C>T | Splice Region (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
- UBA7 | c.2542C>A p.Q848K | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE3B | c.1408T>G p.S470A | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UHRF1BP1 | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 82/631 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC13A | c.3609C>G p.I1203M | Missense Mutation (SNP) | VAF 133/376 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- UNC13C | c.3150+1G>A p.X1050_splice | Splice Site (SNP) | VAF 48/189 reads (25%) | called by muse, mutect2, varscan2
- UNC5C | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 146/465 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP16 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- USP31 | c.3767G>T p.G1256V | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- USP48 | c.2698G>C p.D900H | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- USP48 | c.2099G>C p.R700T | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- USP8 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2, varscan2
- VPS52 | c.763A>G p.N255D | Missense Mutation (SNP) | VAF 108/332 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- VSTM1 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 272/908 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA5A | c.1927C>G p.P643A | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWCE | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- WASHC2C | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 159/490 reads (32%) | called by muse, mutect2, varscan2
- WDFY3 | c.3900A>C p.P1300= | Splice Region (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- WDPCP | c.2076C>T p.N692= | Splice Region (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
- WDR90 | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNT10B | c.-40-5C>A | Splice Region (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2
- WWTR1 | c.1151A>T p.N384I | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ZDBF2 | c.6709A>G p.R2237G | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZKSCAN3 | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZNF10 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ZNF256 | c.1506T>A p.H502Q | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF274 | c.1620dup p.G541Wfs*24 (on ENST00000610905; = p.G436Wfs*24 on NM_016324.3) | Frame Shift Ins (INS) | VAF 81/284 reads (29%) | called by mutect2, pindel, varscan2
- ZNF292 | c.582G>C p.M194I | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF577 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ZNF607 | c.1869del p.K624Rfs*100 | Frame Shift Del (DEL) | VAF 24/123 reads (20%) | called by mutect2, pindel, varscan2
- ZNF611 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF618 | c.719A>G p.E240G (on ENST00000374126 / NM_001318042.2; = p.E208G on NM_133374.2) | Missense Mutation (SNP) | VAF 79/514 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF701 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 53/492 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF831 | c.4226C>A p.T1409N | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF865 | c.2847G>T p.E949D | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZRANB3 | c.638G>T p.W213L | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ZSCAN25 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 155/392 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB1 | c.471A>C p.R157= | Silent (SNP) | VAF 73/375 reads (19%) | called by muse, mutect2, varscan2
- ACSL6 | c.546C>T p.G182= (on ENST00000379240; = p.G207= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/342 reads (18%) | called by muse, mutect2, varscan2
- ADGRA2 | c.2988G>C p.G996= | Silent (SNP) | VAF 46/174 reads (26%) | called by mutect2, varscan2
- AHNAK2 | c.13683C>G p.L4561= | Silent (SNP) | VAF 88/1162 reads (8%) | catalogued as COSV60922450; called by muse, mutect2
- ARID1A | c.2787T>C p.P929= | Silent (SNP) | VAF 70/355 reads (20%) | called by muse, mutect2, varscan2
- B3GAT1 | c.384G>T p.P128= | Silent (SNP) | VAF 70/496 reads (14%) | catalogued as COSV57001031; called by muse, mutect2, varscan2
- BCL9L | c.2379G>A p.Q793= | Silent (SNP) | VAF 45/339 reads (13%) | called by muse, mutect2, varscan2
- BEST3 | c.835C>T p.L279= | Silent (SNP) | VAF 81/201 reads (40%) | called by muse, mutect2, varscan2
- BFAR | c.60C>G p.L20= | Silent (SNP) | VAF 22/696 reads (3%) | called by muse, mutect2
- C1orf127 | c.2367C>A p.L789= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV100983492; called by muse, mutect2, varscan2
- CACNA1B | c.3492C>T p.S1164= | Silent (SNP) | VAF 144/298 reads (48%) | called by muse, mutect2, varscan2
- CACNA1H | c.4947C>G p.L1649= | Silent (SNP) | VAF 77/465 reads (17%) | catalogued as rs1269507586; called by muse, mutect2, varscan2
- CCDC105 | c.369C>G p.T123= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs766208372; called by muse, mutect2, varscan2
- CCDC186 | c.2133A>G p.G711= | Silent (SNP) | VAF 29/186 reads (16%) | called by muse, mutect2, varscan2
- CCNF | c.453C>G p.L151= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as rs775747522; called by muse, mutect2
- CDC42BPA | c.3696A>T p.A1232= (on ENST00000334218 / NM_001366019.2; = p.A1219= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/203 reads (29%) | called by muse, mutect2, varscan2
- CDH15 | c.2436G>A p.R812= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs370773746; called by muse, mutect2, varscan2
- CDT1 | c.156C>G p.R52= | Silent (SNP) | VAF 337/752 reads (45%) | called by muse, mutect2, varscan2
- CHAT | c.2246G>A p.*749= | Silent (SNP) | VAF 242/540 reads (45%) | catalogued as COSV60330082; called by muse, mutect2, varscan2
- CNOT2 | c.972A>G p.T324= | Silent (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
- COL4A2 | c.3300A>G p.P1100= | Silent (SNP) | VAF 89/213 reads (42%) | catalogued as rs920628974; called by muse, mutect2, varscan2
- COLEC12 | c.306C>T p.I102= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV101231960; called by muse, mutect2
- CSNK1A1L | c.183C>T p.S61= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as rs1205241740, COSV65790346; called by muse, mutect2, varscan2
- DCAF8L1 | c.423G>A p.E141= | Silent (SNP) | VAF 71/165 reads (43%) | called by muse, mutect2, varscan2
- DCHS2 | c.1554G>T p.P518= | Silent (SNP) | VAF 48/159 reads (30%) | catalogued as COSV100252175; called by muse, mutect2, varscan2
- DGKZ | c.354G>A p.E118= | Silent (SNP) | VAF 82/624 reads (13%) | called by muse, mutect2, varscan2
- DHX58 | c.534C>T p.L178= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as rs146459535; called by muse, mutect2, varscan2
- DLGAP1 | c.2778G>T p.P926= | Silent (SNP) | VAF 63/315 reads (20%) | called by muse, mutect2, varscan2
- DNAH11 | c.5436G>A p.V1812= | Silent (SNP) | VAF 101/409 reads (25%) | catalogued as rs754198791, COSV60958696; called by muse, mutect2, varscan2
- DOP1B | c.5427G>T p.L1809= | Silent (SNP) | VAF 25/226 reads (11%) | called by muse, mutect2, varscan2
- DPF1 | c.891C>A p.A297= | Silent (SNP) | VAF 93/321 reads (29%) | catalogued as COSV62794032; called by muse, mutect2, varscan2
- DPP6 | c.591T>C p.D197= (on ENST00000377770 / NM_001364500.2; = p.D135= on NM_001936.5) | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV59607126, COSV59643496; called by muse, mutect2, varscan2
- DSE | c.1101G>A p.L367= | Silent (SNP) | VAF 151/511 reads (30%) | catalogued as rs1369213380; called by muse, mutect2, varscan2
- DTWD1 | c.693A>C p.T231= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- EIF4G2 | c.132G>C p.G44= | Silent (SNP) | VAF 131/638 reads (21%) | called by muse, mutect2, varscan2
- EOGT | c.288T>G p.V96= | Silent (SNP) | VAF 85/189 reads (45%) | called by muse, mutect2, varscan2
- EPB41L4B | c.2199A>G p.K733= | Silent (SNP) | VAF 42/248 reads (17%) | called by muse, mutect2, varscan2
- ERAS | c.585G>T p.L195= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- ERICH3 | c.922C>A p.R308= | Silent (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- EXOC6B | c.244C>T p.L82= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV55577296; called by muse, mutect2, varscan2
- FAM234B | c.1008A>T p.I336= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as COSV52195121; called by muse, mutect2, varscan2
- FBN3 | c.390C>T p.C130= | Silent (SNP) | VAF 124/320 reads (39%) | called by muse, mutect2, varscan2
- FMN2 | c.450C>A p.A150= | Silent (SNP) | VAF 95/317 reads (30%) | called by muse, mutect2, varscan2
- GABRB1 | c.1125G>T p.R375= | Silent (SNP) | VAF 68/201 reads (34%) | called by muse, mutect2, varscan2
- GFPT2 | c.1878T>A p.T626= | Silent (SNP) | VAF 129/245 reads (53%) | called by muse, mutect2, varscan2
- GLI1 | c.2466G>C p.V822= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- GPR61 | c.1248C>A p.G416= | Silent (SNP) | VAF 155/363 reads (43%) | called by muse, mutect2, varscan2
- HCN1 | c.2550C>T p.I850= | Silent (SNP) | VAF 57/407 reads (14%) | catalogued as rs772068771, COSV57532195; called by muse, mutect2, varscan2
- HRH1 | c.648C>T p.A216= | Silent (SNP) | VAF 145/304 reads (48%) | catalogued as rs202235368, COSV67955027; called by muse, mutect2, varscan2
- HSPG2 | c.8130C>T p.V2710= | Silent (SNP) | VAF 305/753 reads (41%) | catalogued as COSV101020416; called by muse, mutect2, varscan2
- HTR4 | c.954T>A p.S318= | Silent (SNP) | VAF 66/388 reads (17%) | called by muse, mutect2, varscan2
- HTT | c.5625A>G p.G1875= | Silent (SNP) | VAF 69/253 reads (27%) | called by muse, mutect2, varscan2
- IGF2R | c.5172C>T p.I1724= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs780345931; called by muse, mutect2, varscan2
- IGKV6D-41 | c.27G>C p.R9= | Silent (SNP) | VAF 84/268 reads (31%) | called by muse, mutect2, varscan2
- INPP4B | c.699C>T p.N233= | Silent (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- ITGA11 | c.1209C>T p.V403= | Silent (SNP) | VAF 107/567 reads (19%) | called by muse, mutect2, varscan2
- JPH1 | c.528C>G p.L176= | Silent (SNP) | VAF 59/569 reads (10%) | catalogued as rs773219532; called by muse, mutect2, varscan2
- KCNQ3 | c.2514G>A p.T838= | Silent (SNP) | VAF 119/1296 reads (9%) | catalogued as rs568466967, COSV66470523; called by muse, mutect2
- KCNV1 | c.873G>T p.L291= | Silent (SNP) | VAF 112/592 reads (19%) | called by muse, mutect2, varscan2
- KIF26B | c.1050G>T p.V350= | Silent (SNP) | VAF 82/282 reads (29%) | catalogued as COSV69470382; called by muse, mutect2, varscan2
- KLHL41 | c.417A>T p.L139= | Silent (SNP) | VAF 150/314 reads (48%) | called by muse, mutect2, varscan2
- KMT2B | c.6993G>T p.V2331= | Silent (SNP) | VAF 71/457 reads (16%) | catalogued as rs1296526395; called by muse, mutect2, varscan2
- KRTAP10-5 | c.246C>T p.S82= | Silent (SNP) | VAF 1013/1963 reads (52%) | called by muse, mutect2, varscan2
- LIPE | c.1296G>T p.L432= | Silent (SNP) | VAF 275/943 reads (29%) | catalogued as COSV99734348; called by muse, mutect2, varscan2
- LRP1B | c.4980A>T p.S1660= | Silent (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- MDN1 | c.9930G>T p.L3310= | Silent (SNP) | VAF 50/174 reads (29%) | called by muse, mutect2, varscan2
- MFNG | c.117C>G p.P39= | Silent (SNP) | VAF 58/440 reads (13%) | catalogued as COSV99325042; called by muse, mutect2, varscan2
- MGAM | c.3456G>A p.G1152= | Silent (SNP) | VAF 90/256 reads (35%) | catalogued as COSV101527423; called by muse, mutect2, varscan2
- MGAT5B | c.1749C>G p.P583= (on ENST00000569840 / NM_001199172.2; = p.P581= on NM_144677.3) | Silent (SNP) | VAF 43/209 reads (21%) | catalogued as rs776475033; called by muse, mutect2, varscan2
- MIXL1 | c.243C>G p.A81= | Silent (SNP) | VAF 56/184 reads (30%) | called by muse, mutect2, varscan2
- MUC19 | c.537T>C p.N179= | Silent (SNP) | VAF 28/160 reads (18%) | called by muse, mutect2
- MYBPC2 | c.3084C>G p.L1028= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as COSV63093051; called by muse, mutect2, varscan2
- MYH13 | c.3901C>T p.L1301= | Silent (SNP) | VAF 68/347 reads (20%) | catalogued as COSV52846755; called by muse, mutect2, varscan2
- NALCN | c.1362A>G p.E454= | Silent (SNP) | VAF 31/208 reads (15%) | called by muse, mutect2, varscan2
- NANOS1 | c.36C>A p.R12= | Silent (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2
- NCKAP5 | c.3687A>G p.L1229= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- NOSTRIN | c.168G>A p.L56= | Silent (SNP) | VAF 81/233 reads (35%) | catalogued as COSV58322866; called by muse, mutect2, varscan2
- NPBWR2 | c.336C>T p.F112= | Silent (SNP) | VAF 61/358 reads (17%) | catalogued as rs138941629; called by muse, mutect2, varscan2
- NR5A2 | c.558C>T p.I186= (on ENST00000367362 / NM_205860.3; = p.I140= on NM_003822.5) | Silent (SNP) | VAF 97/321 reads (30%) | called by muse, mutect2, varscan2
- NSD1 | c.1839G>T p.L613= | Silent (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- NUTM2F | c.930G>T p.P310= | Silent (SNP) | VAF 112/298 reads (38%) | called by muse, varscan2
- NWD1 | c.462C>T p.I154= | Silent (SNP) | VAF 195/384 reads (51%) | called by muse, mutect2, varscan2
- OGDH | c.1149G>A p.V383= | Silent (SNP) | VAF 176/1059 reads (17%) | called by muse, varscan2
- OR2J3 | c.498C>A p.T166= | Silent (SNP) | VAF 64/484 reads (13%) | called by muse, mutect2, varscan2
- OR3A1 | c.648C>G p.L216= | Silent (SNP) | VAF 105/532 reads (20%) | catalogued as COSV100041625; called by muse, mutect2, varscan2
- OR4X1 | c.837C>G p.L279= | Silent (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- OR6T1 | c.876C>A p.L292= | Silent (SNP) | VAF 115/664 reads (17%) | called by muse, mutect2, varscan2
- OR8H1 | c.159C>T p.L53= | Silent (SNP) | VAF 34/288 reads (12%) | catalogued as COSV100477190; called by muse, mutect2, varscan2
- PACRGL | c.396T>G p.T132= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- PDHA2 | c.213C>A p.R71= | Silent (SNP) | VAF 111/330 reads (34%) | catalogued as COSV54778172; called by muse, mutect2, varscan2
- PEBP4 | c.543G>A p.L181= | Silent (SNP) | VAF 68/399 reads (17%) | called by muse, mutect2, varscan2
- PGK2 | c.795C>A p.I265= | Silent (SNP) | VAF 94/325 reads (29%) | catalogued as COSV59162610; called by muse, mutect2, varscan2
- PIGR | c.1173G>A p.Q391= | Silent (SNP) | VAF 63/381 reads (17%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.801T>C p.D267= | Silent (SNP) | VAF 60/142 reads (42%) | called by muse, mutect2, varscan2
- POSTN | c.2478T>A p.S826= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- PPP1R3F | c.1590G>T p.T530= | Silent (SNP) | VAF 52/109 reads (48%) | called by muse, mutect2, varscan2
- PRDM12 | c.474G>C p.R158= | Silent (SNP) | VAF 76/486 reads (16%) | called by muse, varscan2
- PRPH | c.555G>A p.E185= | Silent (SNP) | VAF 85/747 reads (11%) | called by muse, mutect2, varscan2
- PRR23C | c.135G>A p.P45= | Silent (SNP) | VAF 127/430 reads (30%) | catalogued as rs745691627, COSV101356535; called by muse, mutect2, varscan2
- PTCHD4 | c.2436T>C p.P812= | Silent (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- QPRT | c.399C>T p.H133= | Silent (SNP) | VAF 81/511 reads (16%) | catalogued as rs769605728, COSV54879671; called by muse, mutect2, varscan2
- SCARF2 | c.798C>T p.G266= | Silent (SNP) | VAF 34/185 reads (18%) | called by muse, mutect2, varscan2
- SCNN1B | c.1422C>A p.V474= | Silent (SNP) | VAF 187/607 reads (31%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1078A>C p.R360= | Silent (SNP) | VAF 148/330 reads (45%) | called by muse, varscan2
- SLC35B4 | c.741C>T p.I247= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs1359411461; called by muse, mutect2, varscan2
- SLC5A6 | c.1323C>A p.L441= | Silent (SNP) | VAF 213/717 reads (30%) | catalogued as COSV100143207; called by muse, mutect2, varscan2
- SMKR1 | c.12A>G p.K4= | Silent (SNP) | VAF 37/204 reads (18%) | called by muse, varscan2
- SPATA18 | c.648G>A p.Q216= | Silent (SNP) | VAF 146/1018 reads (14%) | catalogued as COSV54641661; called by muse, mutect2, varscan2
- SPTA1 | c.2514C>A p.I838= | Silent (SNP) | VAF 133/617 reads (22%) | called by muse, mutect2, varscan2
- SPTBN4 | c.6322C>A p.R2108= | Silent (SNP) | VAF 35/123 reads (28%) | called by muse, mutect2, varscan2
- SSH2 | c.1452C>T p.I484= | Silent (SNP) | VAF 45/238 reads (19%) | called by muse, mutect2, varscan2
- STK10 | c.1626C>A p.I542= | Silent (SNP) | VAF 143/263 reads (54%) | called by muse, mutect2, varscan2
- STT3B | c.2448G>A p.K816= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- SUSD2 | c.1314C>T p.C438= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs771875326; called by muse, mutect2
- SYN3 | c.576C>A p.V192= | Silent (SNP) | VAF 117/298 reads (39%) | called by muse, mutect2, varscan2
- TAS1R2 | c.777C>T p.T259= | Silent (SNP) | VAF 264/629 reads (42%) | catalogued as rs968603222; called by muse, mutect2, varscan2
- TBC1D31 | c.42A>T p.I14= | Silent (SNP) | VAF 443/940 reads (47%) | called by muse, mutect2, varscan2
- THEGL | c.1161G>A p.A387= | Silent (SNP) | VAF 22/218 reads (10%) | catalogued as rs368971975, COSV101557172; called by muse, mutect2
- TMEM86B | c.75G>A p.L25= | Silent (SNP) | VAF 191/570 reads (34%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.1425G>A p.G475= | Silent (SNP) | VAF 140/1508 reads (9%) | catalogued as rs1366500998; called by muse, mutect2
- TRBV2 | c.198T>A p.V66= | Silent (SNP) | VAF 75/433 reads (17%) | called by muse, mutect2, varscan2
- TRIM58 | c.630G>A p.A210= | Silent (SNP) | VAF 366/1179 reads (31%) | catalogued as rs370386549; called by muse, mutect2, varscan2
- TRIML1 | c.120C>T p.L40= | Silent (SNP) | VAF 60/320 reads (19%) | catalogued as COSV60195960; called by muse, mutect2, varscan2
- TTN | c.39129G>A p.V13043= (on ENST00000591111; = p.V5619= on NM_003319.4) | Silent (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- TUBA3C | c.1245G>A p.E415= | Silent (SNP) | VAF 118/513 reads (23%) | called by muse, mutect2, varscan2
- TUBA3D | c.627C>T p.I209= | Silent (SNP) | VAF 104/634 reads (16%) | catalogued as rs759692672; called by mutect2, varscan2
- TXNRD1 | c.1521C>T p.L507= (on ENST00000525566 / NM_001093771.3; = p.L409= on NM_003330.4) | Silent (SNP) | VAF 92/272 reads (34%) | called by muse, mutect2, varscan2
- TYROBP | c.315C>G p.L105= | Silent (SNP) | VAF 170/1163 reads (15%) | called by muse, mutect2, varscan2
- UBASH3B | c.783C>A p.V261= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as COSV52503586; called by muse, mutect2, varscan2
- UBE3A | c.1651T>C p.L551= | Silent (SNP) | VAF 96/440 reads (22%) | called by muse, varscan2
- UBE3B | c.1410G>T p.S470= | Silent (SNP) | VAF 70/321 reads (22%) | catalogued as COSV55090669; called by muse, mutect2
- UPF1 | c.541C>T p.L181= | Silent (SNP) | VAF 222/509 reads (44%) | called by muse, mutect2, varscan2
- USP11 | c.792G>T p.A264= (on ENST00000218348; = p.A221= on NM_001371072.1) | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as COSV54475034; called by muse, mutect2, varscan2
- VWA5B2 | c.2361C>A p.G787= | Silent (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- WDPCP | c.1566C>T p.I522= | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as COSV99706768; called by muse, mutect2, varscan2
- WDR11 | c.3651C>T p.P1217= | Silent (SNP) | VAF 157/418 reads (38%) | catalogued as rs777073868; called by muse, mutect2, varscan2
- ZEB2 | c.735C>G p.L245= | Silent (SNP) | VAF 127/665 reads (19%) | catalogued as rs1431555828, COSV57950475, COSV57957259; called by muse, mutect2, varscan2
- ZFHX3 | c.2742C>T p.D914= | Silent (SNP) | VAF 34/158 reads (22%) | called by muse, mutect2
- ZNF235 | c.2073C>G p.G691= | Silent (SNP) | VAF 49/304 reads (16%) | catalogued as COSV52156583; called by muse, mutect2, varscan2
- ZNF280A | c.639C>A p.I213= | Silent (SNP) | VAF 48/292 reads (16%) | catalogued as COSV100130949, COSV57480036; called by muse, mutect2, varscan2
- ZNF3 | c.1065C>G p.L355= | Silent (SNP) | VAF 97/231 reads (42%) | called by muse, mutect2, varscan2
- ZNF471 | c.297G>A p.K99= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- ZNF566 | c.39A>C p.V13= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV101091498; called by muse, mutect2, varscan2
- ZNF583 | c.1647T>C p.T549= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- ZNF845 | c.2814T>C p.T938= | Silent (SNP) | VAF 48/226 reads (21%) | catalogued as rs561834019, COSV101508957; called by muse, mutect2, varscan2
- ZWILCH | c.1464C>G p.L488= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs768006361; called by muse, mutect2, varscan2
- AC022182.1 | n.669A>G | RNA (SNP) | VAF 34/160 reads (21%) | called by muse, varscan2
- AC073343.1 | n.148G>T | RNA (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.690G>T | RNA (SNP) | VAF 143/554 reads (26%) | called by muse, mutect2, varscan2
- AFDN | chr6:167976132 del G | 3'Flank (DEL) | VAF 93/367 reads (25%) | called by mutect2, pindel, varscan2
- ANP32A | c.54+2468C>G | Intron (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- API5 | c.*81C>T | 3'UTR (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.*612C>G | 3'UTR (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- ARL15 | c.463-64862C>G | Intron (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- BACE1 | c.262-2704G>C | Intron (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- BOD1P2 | n.283G>C | RNA (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
- BTBD11 | c.1135+545C>T | Intron (SNP) | VAF 103/661 reads (16%) | called by muse, mutect2, varscan2
- CIT | c.2779-12C>T | Intron (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- DACH2 | c.*69A>T | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2
- DAO | c.*48T>C | 3'UTR (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- DAOA | c.282-107G>A | Intron (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- DBI | c.-90C>G | 5'UTR (SNP) | VAF 44/277 reads (16%) | called by muse, mutect2, varscan2
- DCAF17 | c.*3402G>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- DTX2 | c.1151-32C>G | Intron (SNP) | VAF 161/1508 reads (11%) | called by muse, mutect2, varscan2
- FBXL13 | c.496-5607G>T | Intron (SNP) | VAF 55/428 reads (13%) | called by muse, mutect2, varscan2
- FHL2 | chr2:105399417 ins G | 5'Flank (INS) | VAF 47/297 reads (16%) | called by mutect2, pindel, varscan2
- FOXL2 | c.-19G>C | 5'UTR (SNP) | VAF 47/534 reads (9%) | called by muse, mutect2
- FSHR | c.-43C>G | 5'UTR (SNP) | VAF 141/378 reads (37%) | called by muse, mutect2, varscan2
62 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 62 other) are not listed here.
